CCDI case PBBXMR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/5d0b95bc-a7d2-4ff8-9da9-8edf9b8ea228

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 11.2 years (4,104 days).

Biospecimens (3 samples)
- Sample 0DKF9M: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKF9T: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKFA7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
